HCMI case HCM-BROD-1099-C84 — NCI Cancer Model Development for the Human Cancer Model Initiative (HCMI-CMDC)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Mature T- and NK-Cell Lymphomas; Primary site: Lymph nodes. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/5e2f613c-4a63-44da-b367-329c9245a762

Demographics
Sex at birth: female; Ethnicity: not hispanic or latino; Year of birth: 1972; Vital status: Dead; Days to death: 385 days (1.1 years); Cause of death: Cancer Related.

Diagnoses (1)
1. Mature T-cell lymphoma, NOS: ICD-O-3 morphology code: 9702/3; ICD-10 code: C84.4; Tissue or organ of origin: Lymph node, NOS; Site of resection or biopsy: Blood; Classification of tumor: primary; Age at diagnosis: 43.0 years (15,723 days); Ann Arbor clinical stage: Stage III; Tumor grade: GX; Prior malignancy: no; Prior treatment: Yes.
   Pathology details: Lymph node involved site: Cervical, NOS; Lymph nodes positive: 1; Lymph nodes tested: 1; Lymphatic invasion present: Yes.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Carboplatin + Cyclophosphamide + Doxorubicin + Etoposide + Ifosfamide + Prednisone + Romidepsin + Vincristine; Treatment intent type: Neoadjuvant; Days to treatment start: 19 days.
   Treatment given: Treatment type: Immunotherapy (Including Vaccines); Treatment intent type: Neoadjuvant; Days to treatment start: 274 days.
   Recorded as not given: adjuvant Pharmaceutical Therapy, NOS, for residual disease; neoadjuvant Radiation Therapy, NOS; Surgery, NOS, for initial diagnosis.

Follow-up (1 entry)
- Days to follow up: 385 days (1.1 years); Disease response: Progressive Disease; Progression or recurrence: Yes.

Molecular and laboratory tests
- Lactate Dehydrogenase 591.
- Leukocytes 36.2 ×10³/µL.
- Hemoglobin 9.4 g/dL.
- Hematocrit 30%.
- Platelets 384 ×10³/µL.

Other clinical attributes
- Timepoint category: Initial Diagnosis; Weight: 80 kg; Height: 160 cm; BMI: 25.

Exposures
- Tobacco smoking status: Lifelong Non-Smoker; Alcohol drinks per day: 0; Alcohol days per week: 0.

Family history
- Relative with cancer history: yes; Relationship type: First Degree Relative, NOS; Relationship primary diagnosis: Cancer.

Biospecimens (1 sample)
- Sample HCM-BROD-1099-C84-85B: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Adherent Cell Line; Preservation method: Frozen; Passage count: 9.
